Surgical pathology report (de-identified scan), TCGA case TCGA-5C-A9VG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Cureline, specimen TCGA-5C-A9VG-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** M

Clinical diagnosis: Primary liver cancer

Date of procurement:

Sample: histology #

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Op 1/27/14

Gross description: Right lobe of the liver and gall bladder single block
23x17x11,,5 cm . 1,8 cm from resection line liver parenchyma shows nodular
mass20x12x10 cm partially covered with capsule soft consistency. Section
shows gray color mass with necrotic nests, there is no infiltration of the liver
capsule. Gall bladder 8x5cm with smooth surface, greenish-brownish. Lymphatic
node from common hepatic artery area is 4,5x2,5 cm . Section shows dense
consistency cyanotic color.

Microscopic description:. Surgical margins are clear .Nodular mass shows
signs of hepatocellular cancer with different degree of differentiation (G2) with
polumorphic cells and elements of acinar and clear cells. Tumor infiltrates
hepatic parenchyma and vessels. Hepatic parenchyma shows signs of lymphoid
infiltration

Lymphatic nodes show no signs of tumor growth.

Gallbladder shows signs of autolysis.

Final diagnosis Hepatocellular carcinoma

Confidential

Criteria	kw 12/20/13	Yes	No

Source: NCI Genomic Data Commons file 86f305c9-e9aa-4bd4-bbda-f107e5373a7f (TCGA-5C-A9VG.9C941E66-614A-49E4-8C60-2C040C591A11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).